Somatic mutation profile of tumor specimen TCGA-CD-8528-01A (aliquot TCGA-CD-8528-01A-11D-2340-08) from TCGA case TCGA-CD-8528, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 43.8 years (15,986 days).
Specimen TCGA-CD-8528-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3502f001-74b5-4035-9abf-b57796b8d46a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8528-10A (Blood Derived Normal), aliquot TCGA-CD-8528-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9406ed5-2867-435e-97ce-f516df0849eb

The open-access MAF lists 102 somatic variants for this specimen: 78 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 21, Nonsense Mutation 6, Intron 2, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAG1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918351, CM981095, CM992632, COSV54757968; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 14/20 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs148839428, COSV62322288; called by muse, mutect2, varscan2
- ABCC9 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.495); catalogued as rs143685061; ClinVar: uncertain significance; called by muse, mutect2
- ACRBP | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs779126758, COSV57524579; called by muse, mutect2, varscan2
- ADAP2 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV58296477; called by muse, mutect2, varscan2
- AIFM3 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.09); catalogued as rs1008206831, COSV99301436; called by mutect2, varscan2
- ARFGEF2 | c.4724A>C p.K1575T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV64213471; called by muse, mutect2, varscan2
- ASTN2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs748550947, COSV100526472, COSV57751743; called by muse, mutect2, varscan2
- ATAD3A | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as rs1308954605; called by muse, mutect2
- ATP10A | c.3358C>A p.Q1120K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV63519939; called by muse, mutect2, varscan2
- ATP13A2 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs781304413, COSV58701746; called by muse, mutect2
- BSN | c.1136C>A p.P379H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV56522080; called by muse, mutect2, varscan2
- CACNA1C | c.5329C>T p.R1777C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs775251529, COSV59740671; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CBLN4 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756451061, COSV50352834; called by muse, mutect2, varscan2
- CDCA3 | c.494G>C p.S165T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); catalogued as COSV57529510; called by muse, mutect2, varscan2
- CENPF | c.6134A>G p.Q2045R | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.452); catalogued as COSV65276374; called by muse, mutect2, varscan2
- CHSY3 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as rs201309375, COSV59281128; called by muse, mutect2
- CNTN6 | c.1658G>T p.R553M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.968); catalogued as COSV63164140, COSV63178840; called by muse, mutect2, varscan2
- CPNE9 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.393); catalogued as rs758908204, COSV56069063; called by muse, mutect2, varscan2
- CRYGD | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV52205653; called by muse, mutect2, varscan2
- CSMD3 | c.5606C>A p.A1869D (on ENST00000297405 / NM_001363185.1; = p.A1765D on NM_052900.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV52181856; called by muse, mutect2, varscan2
- CYP2A13 | c.1275G>C p.K425N | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV57838768; called by muse, mutect2, varscan2
- DLGAP1 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100229751, COSV59816231; called by muse, mutect2, varscan2
- DSEL | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV59492755; called by muse, mutect2, varscan2
- EEF1E1 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV65675816; called by muse, mutect2, varscan2
- ELAPOR2 | c.1828G>A p.G610S (on ENST00000450689 / NM_001142749.3; = p.G443S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.095); catalogued as rs778431064, COSV51888589; called by muse, mutect2, varscan2
- EVA1C | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs762283599, COSV55825207; called by muse, mutect2, varscan2
- FAM47C | c.2866C>A p.P956T | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV63727072; called by muse, mutect2, varscan2
- FGF12 | c.355C>T p.Q119* (on ENST00000454309 / NM_021032.5; = p.Q57* on NM_004113.6) | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV53175053; called by muse, mutect2, varscan2
- FLG | c.9940A>T p.R3314* | Nonsense Mutation (SNP) | VAF 89/610 reads (15%) | catalogued as COSV64244155; called by muse, mutect2, varscan2
- FLG | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 149/363 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs200858156, COSV64243479; called by muse, mutect2, varscan2
- FMO5 | c.64T>C p.C22R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54208318; called by muse, mutect2, varscan2
- FRAS1 | c.7768C>T p.R2590C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs368735572; called by muse, mutect2, varscan2
- GALNTL5 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs368842809, COSV67180145; called by muse, mutect2, varscan2
- GRPR | c.314G>T p.R105I | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV66669826; called by muse, mutect2, varscan2
- HAND2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64018496; called by muse, mutect2, varscan2
- KAT8 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1362778508, COSV54897633; called by muse, mutect2
- KLHDC4 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs867724471, COSV54507758; called by muse, mutect2
- LILRA5 | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV56643815; called by muse, mutect2, varscan2
- MAN1A2 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as COSV62979455; called by muse, mutect2, varscan2
- MAPK1IP1L | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); catalogued as rs1340772506, COSV67106552; called by muse, mutect2, varscan2
- MED13 | c.2825G>C p.S942T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV67265002; called by muse, mutect2, varscan2
- MME | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs184108383, COSV64706271; called by muse, mutect2, varscan2
- NCOA1 | c.3484G>A p.G1162S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV56048074; called by muse, mutect2, varscan2
- NSMAF | c.459T>A p.L153= | Splice Region (SNP) | VAF 25/90 reads (28%) | catalogued as COSV50691550; called by muse, mutect2, varscan2
- NUP58 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV67751154; called by muse, mutect2, varscan2
- OR2T1 | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV63542391; called by muse, mutect2, varscan2
- OR5M3 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs769332657, COSV56566646; called by muse, mutect2, varscan2
- PCOLCE2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs376768304; called by muse, mutect2, varscan2
- PDE1C | c.489A>C p.L163F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.714); catalogued as rs758343492, COSV58519367; called by muse, mutect2, varscan2
- PHF2 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1434809621, COSV63682054; called by muse, mutect2, varscan2
- PRAMEF12 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs748990477, COSV63214639; called by muse, mutect2, varscan2
- PRX | c.3832G>A p.D1278N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs377639106; called by muse, mutect2
- PTPRN2 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV67047767; called by muse, mutect2, varscan2
- PWWP3B | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs771260235, COSV61800613; called by muse, mutect2, varscan2
- RPS6KA6 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs200685475, COSV53116531, COSV53124777; called by muse, mutect2, varscan2
- SCG2 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.27); catalogued as rs763799045, COSV59539138, COSV59539511; called by muse, mutect2, varscan2
- SEC14L2 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV57241704; called by muse, mutect2, varscan2
- SHANK1 | c.3419C>T p.P1140L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53255323; called by muse, mutect2
- SLC36A2 | c.1214T>G p.L405R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58863998; called by muse, mutect2
- SLC9C2 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs539570027, COSV62946320, COSV62947742; called by muse, mutect2, varscan2
- SSTR4 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV54798610; called by muse, mutect2, varscan2
- SYNGR2 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs370411109; called by muse, mutect2, varscan2
- TAOK1 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV55594656; called by muse, mutect2, varscan2
- TENM1 | c.4972G>A p.E1658K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as rs377378434, COSV64436491; called by muse, mutect2, varscan2
- TMTC2 | c.439T>G p.F147V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV58274918; called by muse, mutect2, varscan2
- TNC | c.3925C>T p.R1309C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs975197014, COSV60786586; called by muse, mutect2, varscan2
- TPO | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs748124213, COSV61095654; called by muse, mutect2, varscan2
- TUBGCP3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs770585945, COSV56188599; called by muse, mutect2, varscan2
- UGT3A1 | c.649A>G p.M217V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs184564491, COSV57100052; called by muse, mutect2, varscan2
- ULK2 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1022680609, COSV64444719; called by muse, mutect2, varscan2
- UVSSA | c.464C>G p.A155G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV66230280; called by muse, mutect2
- WDCP | c.1193T>G p.L398R | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV54592878; called by muse, mutect2, varscan2
- ZNF124 | c.851A>T p.H284L (on ENST00000543802 / NM_001297568.1; = p.H222L on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61507577; called by muse, mutect2, varscan2
- ZNF831 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV64042251; called by muse, mutect2, varscan2
- EZH1 | c.1205_1206del p.E402Gfs*2 | Frame Shift Del (DEL) | VAF 22/47 reads (47%) | called by pindel, varscan2
- ZNF658 | c.842A>T p.K281I | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ADAMTSL4 | c.3123C>T p.P1041= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs1467251510, COSV55002662; called by muse, mutect2, varscan2
- ARHGAP45 | c.1425G>T p.T475= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs770074601, COSV57433711; called by muse, mutect2, varscan2
- C12orf40 | c.1713C>T p.C571= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV61134675; called by muse, mutect2, varscan2
- CACNA1B | c.522C>T p.V174= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs199849222, COSV53134971; called by muse, mutect2, varscan2
- CLEC17A | c.387T>C p.C129= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV60428634; called by muse, mutect2
- COL11A1 | c.1233T>C p.I411= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs1239789548, COSV62188817; called by muse, mutect2, varscan2
- CRISP3 | c.258C>G p.P86= (on ENST00000371159 / NM_001368123.1; = p.P68= on NM_006061.4) | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV53821653; called by muse, mutect2, varscan2
- DNAH10 | c.13020C>T p.I4340= (on ENST00000409039; = p.I4279= on NM_207437.3) | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs776459972, COSV53020540; called by muse, mutect2, varscan2
- DRC1 | c.2013C>T p.S671= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV55508812; called by muse, mutect2, varscan2
- DSCAML1 | c.492C>T p.T164= (on ENST00000321322; = p.T104= on NM_020693.4) | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as rs778236821, COSV58384815, COSV58398567; called by muse, mutect2, varscan2
- FAT1 | c.3831C>T p.T1277= | Silent (SNP) | VAF 45/178 reads (25%) | catalogued as rs553222395, COSV71672074; called by muse, mutect2, varscan2
- MCM4 | c.2568T>C p.T856= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV50626241; called by muse, mutect2, varscan2
- NFATC1 | c.864C>T p.H288= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs200962841, COSV53703770; called by muse, mutect2, varscan2
- PDIA4 | c.1770C>T p.D590= (on ENST00000286091 / NM_001371244.1; = p.D589= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs370731622, COSV53726305; called by muse, mutect2, varscan2
- PLD4 | c.1116C>T p.R372= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV66915456; called by muse, mutect2
- PTPRN2 | c.597G>A p.T199= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs200623903, COSV67047773; called by muse, mutect2, varscan2
- REV3L | c.7980T>C p.L2660= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV62620851; called by muse, mutect2, varscan2
- SEC14L4 | c.279C>T p.Y93= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs754750771, COSV55400397; called by muse, mutect2, varscan2
- SEMG2 | c.714C>A p.L238= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as COSV65647662; called by muse, mutect2, varscan2
- SLC25A37 | c.732C>T p.A244= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs375263954; called by muse, mutect2, varscan2
- SLC45A1 | c.1383C>T p.D461= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs954614646, COSV57093889; called by muse, mutect2, varscan2
- CR1 | c.487+12157C>T | Intron (SNP) | VAF 43/197 reads (22%) | catalogued as COSV100887544; called by muse, mutect2, varscan2
- MIR380 | n.39G>A | RNA (SNP) | VAF 6/20 reads (30%) | catalogued as rs763781233; called by muse, mutect2, varscan2
- NIBAN3 | c.1844-1460C>G | Intron (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99394987; called by muse, mutect2, varscan2
